Surgical pathology report (de-identified scan), TCGA case TCGA-5R-AA1C, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Proteogenex, Inc, specimen TCGA-5R-AA1C-01A (Primary Tumor).

Age/Sex: years / M

Date:

Procedure: Right hemihepatectomy, cholecystectomy

ICD O-3
Carcinoma, hepatocellular NOS
8/76/13
Site Liver C22.0
9/21/27/14

Preoperative diagnosis: CARCINOMA OF THE LIVER

Postoperative diagnosis: SEE MICROSCOPIC DIAGNOSIS BELOW

Specimen(s): 1. LIVER, RIGHT LOBE 2. GALLBLADDER 3. HEPATODUODENAL LYMPH NODES

Diagnosis:

1. LIVER, RIGHT LOBE:

- Moderately differentiated hepatocellular carcinoma
- Vascular invasion is present
- Remaining hepatic tissue shows fatty dystrophy
- Metavir fibrosis score 1, Knodell histological activity index score 1, Ishak fibrosis score 1
- Resection margin is free of tumor

2. GALLBLADDER:

- Autolysis of the mucosa

3. HEPATODUODENAL LYMPH NODES:

- Lymph node is negative for metastatic carcinoma

Gross description:

1. LIVER, RIGHT LOBE:

Received fresh, is a right lobe of the liver 22.5 x 20.0 x 8.5 cm in dimensions. At a distance of 2.5 cm from the resection margin the flabby lobulated yellowish-brown tumor 15.0 x 9.5 x 9.5 cm in dimensions is present. The remaining hepatic tissue is flabby and yellowish-brown.

2. GALLBLADDER:

Received fresh, is a gallbladder 8.0 x 5.0 x 2.0 cm in dimensions with a smooth greenish serosa and a plush greenish mucosa. The gallbladder contains greenish bile.

3. HEPATODUODENAL LYMPH NODES:

Received fresh, is a portion of adipose tissue with a lymph node 0.7 cm in diameter.

Case is (di-):		

Source: NCI Genomic Data Commons file 73401683-5109-459f-8ad4-827dc48f23ac (TCGA-5R-AA1C.AF0BACCE-3975-4E9F-9272-404229EC77C9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).